Somatic mutation profile of tumor specimen TCGA-BP-5183-01A (aliquot TCGA-BP-5183-01A-01D-1429-08) from TCGA case TCGA-BP-5183, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 57.2 years (20,881 days).
Specimen TCGA-BP-5183-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fab9b07-b34f-49fc-b02a-d2f698c25871.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5183-11A (Solid Tissue Normal), aliquot TCGA-BP-5183-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a137931-40c7-47a8-a45f-147e3d1d1c13

The open-access MAF lists 53 somatic variants for this specimen: 40 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 24, Silent 13, Frame Shift Del 9, Nonsense Mutation 5, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABI2 | c.1198G>T p.D400Y (on ENST00000295851 / NM_001375719.1; = p.D362Y on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.964); catalogued as COSV53692207, COSV53694507; called by muse, mutect2, varscan2
- ACKR3 | c.241T>A p.C81S | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV56022879; called by muse, mutect2, varscan2
- ADA2 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 44/120 reads (37%) | catalogued as COSV52832582; called by muse, mutect2, varscan2
- ARF1 | c.181A>C p.I61L | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); catalogued as COSV55255445; called by muse, mutect2, varscan2
- CSMD3 | c.3502G>T p.E1168* (on ENST00000297405 / NM_001363185.1; = p.E1064* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 26/114 reads (23%) | catalogued as COSV52257647; called by muse, mutect2, varscan2
- CSMD3 | c.1844G>T p.R615M (on ENST00000297405 / NM_001363185.1; = p.R511M on NM_052900.3) | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV52108294, COSV52257669; called by muse, mutect2
- CTSB | c.176G>T p.C59F | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1563407049, COSV61541047; called by muse, mutect2, varscan2
- GP2 | c.670C>T p.Q224* (on ENST00000381362 / NM_001007240.3; = p.Q221* on NM_001502.4) | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as rs538424340, COSV56895557; called by muse, mutect2, varscan2
- GPR150 | c.690G>T p.Q230H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV66168206; called by muse, mutect2
- HOXD11 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV50912258; called by muse, mutect2
- IGHV3-49 | c.215G>A p.S72N | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.001); catalogued as rs530514815; called by muse, mutect2, varscan2
- ITGA9 | c.2705_2717del p.H902Lfs*11 | Frame Shift Del (DEL) | VAF 88/225 reads (39%) | catalogued as COSV53248253; called by mutect2, pindel, varscan2
- KEAP1 | c.1226T>C p.M409T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV50525223; called by muse, mutect2, varscan2
- KRBA2 | c.657A>T p.K219N | Missense Mutation (SNP) | VAF 92/274 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV58779401; called by muse, mutect2, varscan2
- MCPH1 | c.1528T>G p.C510G | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV60917136; called by muse, mutect2, varscan2
- NCOA3 | c.2808C>G p.N936K | Missense Mutation (SNP) | VAF 119/378 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV59071302; called by muse, mutect2, varscan2
- NEK3 | c.1175G>A p.G392D | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.677); catalogued as COSV51618389; called by muse, mutect2, varscan2
- NOS1AP | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV62638066; called by muse, mutect2, varscan2
- PPP1R2 | c.500A>T p.D167V | Missense Mutation (SNP) | VAF 20/439 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); catalogued as COSV60498191; called by muse, mutect2
- RABGGTB | c.203G>C p.R68T | Missense Mutation (SNP) | VAF 69/258 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs748832608, COSV60638372; called by muse, mutect2, varscan2
- RIPPLY3 | c.235G>C p.V79L | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV61566969; called by muse, mutect2, varscan2
- RPS6KC1 | c.1027C>G p.L343V | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV65301534; called by muse, mutect2, varscan2
- SEPTIN3 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 59/183 reads (32%) | catalogued as COSV52173374; called by muse, mutect2, varscan2
- STX8 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.205); catalogued as COSV60493731; called by muse, mutect2, varscan2
- SYF2 | c.643A>T p.N215Y | Missense Mutation (SNP) | VAF 141/435 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52574070; called by muse, mutect2, varscan2
- TMX3 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55186622; called by muse, mutect2, varscan2
- VHL | c.392del p.N131Tfs*28 | Frame Shift Del (DEL) | VAF 100/251 reads (40%) | catalogued as COSV56549082; called by mutect2, pindel, varscan2
- XPO1 | c.2950T>C p.S984P | Missense Mutation (SNP) | VAF 57/256 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV68946979; called by muse, mutect2, varscan2
- ZNF568 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.232); catalogued as COSV61742391; called by muse, mutect2, varscan2
- CLDN10 | c.200del p.I67Tfs*4 | Frame Shift Del (DEL) | VAF 27/108 reads (25%) | called by mutect2, pindel, varscan2
- FREM1 | c.5568del p.P1857Lfs*47 | Frame Shift Del (DEL) | VAF 107/262 reads (41%) | called by mutect2, pindel, varscan2
- ITSN1 | c.4543del p.M1515Cfs*8 | Frame Shift Del (DEL) | VAF 42/129 reads (33%) | called by mutect2, pindel, varscan2
- PBRM1 | c.1713dup p.E572* | Frame Shift Ins (INS) | VAF 49/148 reads (33%) | called by mutect2, pindel, varscan2
- PGAM2 | c.394_398del p.Y132Qfs*4 | Frame Shift Del (DEL) | VAF 21/73 reads (29%) | called by mutect2, pindel, varscan2
- POLR2A | c.4627G>A p.A1543T | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.299); called by muse, varscan2
- POLR2A | c.4695G>A p.W1565* | Nonsense Mutation (SNP) | VAF 70/232 reads (30%) | called by muse, varscan2
- SH3BP4 | c.496_497del p.Q166Dfs*17 | Frame Shift Del (DEL) | VAF 64/229 reads (28%) | called by mutect2, pindel, varscan2
- UACA | c.1643_1644insTA p.L549Tfs*2 | Frame Shift Ins (INS) | VAF 142/507 reads (28%) | called by mutect2, pindel, varscan2
- VWA2 | c.723del p.C242Vfs*43 | Frame Shift Del (DEL) | VAF 44/140 reads (31%) | called by mutect2, pindel, varscan2
- ZNF266 | c.451del p.T151Qfs*25 | Frame Shift Del (DEL) | VAF 85/315 reads (27%) | called by mutect2, pindel, varscan2
- CAB39 | c.699C>T p.L233= | Silent (SNP) | VAF 59/214 reads (28%) | catalogued as rs910890819, COSV51478173; called by muse, mutect2, varscan2
- CHAT | c.849C>T p.P283= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs1342051924, COSV60329520; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNKSR1 | c.1590G>A p.E530= (on ENST00000374253 / NM_001297647.2; = p.E523= on NM_006314.3) | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1246377272, COSV58794027; called by muse, mutect2, varscan2
- DOCK5 | c.1215C>G p.L405= | Silent (SNP) | VAF 53/174 reads (30%) | catalogued as COSV52407371; called by muse, mutect2, varscan2
- FAM83A | c.501T>C p.D167= | Silent (SNP) | VAF 83/413 reads (20%) | catalogued as COSV52686655; called by muse, mutect2, varscan2
- HNRNPA1 | c.561T>G p.A187= | Silent (SNP) | VAF 7/134 reads (5%) | catalogued as COSV52937967; called by muse, mutect2
- PSG1 | c.447C>T p.P149= | Silent (SNP) | VAF 115/320 reads (36%) | catalogued as rs757940793, COSV54953951; called by muse, mutect2, varscan2
- RAPGEF6 | c.1071A>C p.G357= | Silent (SNP) | VAF 52/251 reads (21%) | catalogued as COSV57251571; called by muse, mutect2, varscan2
- SLC6A16 | c.1515G>A p.L505= | Silent (SNP) | VAF 72/235 reads (31%) | catalogued as COSV60029207; called by muse, mutect2, varscan2
- TPR | c.5310A>G p.T1770= | Silent (SNP) | VAF 79/256 reads (31%) | catalogued as COSV66603403; called by muse, mutect2, varscan2
- TRERF1 | c.1629C>T p.L543= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as COSV61675312; called by muse, mutect2, varscan2
- UBE2O | c.2460C>A p.I820= | Silent (SNP) | VAF 121/406 reads (30%) | catalogued as COSV60065781; called by muse, varscan2
- ZNF257 | c.348C>A p.G116= | Silent (SNP) | VAF 39/142 reads (27%) | catalogued as rs762029484, COSV71309967, COSV71310416; called by muse, mutect2, varscan2
